Somatic mutation profile of tumor specimen TCGA-AC-A6IX-06A (aliquot TCGA-AC-A6IX-06A-11D-A32I-09) from TCGA case TCGA-AC-A6IX, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 49.2 years (17,969 days).
Specimen TCGA-AC-A6IX-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb3f7c29-8973-4183-a8b4-59e88fa5ae1a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AC-A6IX-10A (Blood Derived Normal), aliquot TCGA-AC-A6IX-10A-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d603a07f-ac17-4bac-90e6-555e863bd1a8

The open-access MAF lists 40 somatic variants for this specimen: 29 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 10, Nonsense Mutation 2, Frame Shift Del 2, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADPRH | c.672A>T p.Q224H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV100813289; called by muse, mutect2, varscan2
- AIFM1 | c.1502G>A p.S501N | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.408); catalogued as COSV99780879; called by muse, mutect2, varscan2
- ALMS1 | c.11134G>C p.E3712Q | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100041737; called by muse, mutect2, varscan2
- B4GALNT3 | c.2236G>A p.E746K | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.85); catalogued as rs553861974, COSV99843630; called by muse, mutect2
- CLIP1 | c.3766G>A p.V1256I (on ENST00000620786 / NM_001247997.1; = p.V1245I on NM_002956.2) | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.037); catalogued as COSV100211428; called by muse, mutect2
- CPT1C | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1477576811, COSV54920207, COSV99773483; called by muse, mutect2, varscan2
- DNAJC5G | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs745899221, COSV99940662; called by muse, mutect2, varscan2
- ERCC6L | c.2710G>A p.E904K | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100559272; called by muse, mutect2, varscan2
- FBXO25 | c.1028C>G p.P343R (on ENST00000382824 / NM_183421.2; = p.P267R on NM_012173.3) | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99366815; called by muse, mutect2, varscan2
- GFOD2 | c.1119C>G p.N373K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.111); catalogued as COSV99263461; called by muse, mutect2, varscan2
- LPAR6 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1422919265, COSV99923844; called by muse, mutect2
- MAK | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100504705; called by muse, mutect2
- MCRS1 | c.405G>A p.W135* | Nonsense Mutation (SNP) | VAF 7/60 reads (12%) | catalogued as COSV100657327; called by muse, mutect2, varscan2
- MEN1 | c.1084G>C p.D362H | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM021294, COSV99580601; called by muse, mutect2, varscan2
- MUC6 | c.6445C>T p.H2149Y | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.052); catalogued as COSV101424467; called by mutect2, varscan2
- MYOM2 | c.2609G>A p.R870H | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs144235879; called by muse, mutect2, varscan2
- PAN2 | c.2635C>T p.H879Y (on ENST00000425394 / NM_001127460.3; = p.H875Y on NM_014871.5) | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as COSV99228181; called by muse, mutect2, varscan2
- PRRC2A | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as COSV63224868; called by muse, mutect2
- RLF | c.3224C>T p.S1075L | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV65652396; called by muse, mutect2, varscan2
- SETD2 | c.6229C>T p.R2077* | Nonsense Mutation (SNP) | VAF 11/80 reads (14%) | catalogued as rs1205330893, COSV57434124; called by muse, mutect2, varscan2
- SLC9A8 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs760094888, COSV64291897; called by muse, mutect2, varscan2
- TOM1 | c.366G>A p.Q122= | Splice Region (SNP) | VAF 14/39 reads (36%) | catalogued as COSV101147103; called by muse, mutect2, varscan2
- TRHR | c.1153G>C p.D385H | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.19); catalogued as COSV100304757; called by muse, mutect2, varscan2
- TRMT2B | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100105263; called by muse, mutect2, varscan2
- VPS13C | c.4199C>T p.S1400L (on ENST00000644861 / NM_020821.3; = p.S1357L on NM_017684.5) | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99827787; called by muse, mutect2, varscan2
- WDR44 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.78); catalogued as COSV99561975; called by muse, mutect2
- ADAMTSL5 | c.1366_1367del p.P456Cfs*32 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | called by mutect2, pindel, varscan2
- CDH1 | c.1709del p.N570Mfs*14 | Frame Shift Del (DEL) | VAF 11/78 reads (14%) | called by mutect2, pindel, varscan2
- ALG1 | c.1246C>T p.L416= | Silent (SNP) | VAF 33/234 reads (14%) | catalogued as rs1471589709, COSV99275551; called by muse, mutect2, varscan2
- BCAR3 | c.102C>G p.L34= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as COSV53077307, COSV99550482; called by muse, mutect2, varscan2
- CRKL | c.90C>T p.G30= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as COSV100574206; called by muse, mutect2, varscan2
- KIF26B | c.2550C>T p.S850= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as rs765221697, COSV100831884; called by muse, mutect2, varscan2
- MYCBP2 | c.2487C>T p.I829= (on ENST00000357337; = p.I867= on NM_015057.5) | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100631990; called by muse, mutect2, varscan2
- PCDHA2 | c.144C>T p.I48= | Silent (SNP) | VAF 23/139 reads (17%) | catalogued as COSV100973709, COSV65365365; called by muse, mutect2, varscan2
- PCLO | c.10341G>A p.T3447= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs566457960, COSV61615170, COSV61629759; called by muse, mutect2, varscan2
- SLC27A1 | c.1314C>T p.L438= | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as COSV99393118; called by muse, mutect2, varscan2
- TBCC | c.288A>G p.K96= | Silent (SNP) | VAF 32/254 reads (13%) | catalogued as COSV99773942; called by muse, mutect2, varscan2
- TRAV12-2 | c.327C>T p.L109= | Silent (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- KIR3DL2 | chr19:54847792 G>A | 5'Flank (SNP) | VAF 34/317 reads (11%) | called by muse, mutect2, varscan2
